Surgical pathology report (de-identified scan), TCGA case TCGA-BB-7861, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-7861-01A (Primary Tumor).

[page 1 of 3]
[REDACTED]

INTERPRETATION AND DIAGNOSIS: [REDACTED]

1,2. TONGUE BASE (BIOPSIES):

HPV RELATED SQUAMOUS CELL CARCINOMA.

NOTE: Immunohistochemical stains for cytokeratin AE1/3 highlight the tumor cells in both parts 1 and 2. In part 1, an immunohistochemical stain for P16 is positive and an in situ hybridization study for high risk HPV is positive.

3. LEFT TONGUE (BIOPSY):

CHRONIC INFLAMMATION AND LYMPHOID HYPERPLASIA. NEGATIVE FOR TUMOR.

4. LYMPH NODES, LEVELS 2 AND 3 RIGHT NECK (DISSECTION):

METASTATIC SQUAMOUS CELL CARCINOMA INVOLVING ONE (1) OF ELEVEN (11) LYMPH NODES. THE METASTATIC FOCUS MEASURES 2.5 CM. NO EXTRANODAL EXTENSION IDENTIFIED.

5. LYMPH NODE, LEVEL 1 (EXCISION):

ONE (1) BENIGN LYMPH NODE.

NOTE: This case was shown at the Daily Quality Assurance Conference.

[REDACTED]

*Electronic signature by which I attest that the above diagnosis is based upon my personal examination of the slides (and / or other material indicated in the diagnosis), and that I have reviewed and approved this report.

=====
Clinical History:
TONGUE BIOPSY

GROSS DESCRIPTION

PART #1: FS: TONGUE BASE BIOPSY [REDACTED]
Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

STAFF PATHOLOGIST: [REDACTED]

FS: Tongue base biopsy: Scattered atypical multinucleated cells of

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 2 of 3]
undetermined significance, defer to permanents.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'tongue base biopsy.' The specimen consists of four fragments of pink-tan soft tissue measuring 0.4 x 0.4 x 0.2 cm in aggregate. The specimen is submitted in its entirety for frozen and then submitted for frozen section control.

SUMMARY OF SECTIONS

1 - FSC - 4 (TONGUE BASE BIOPSY)
1 - TOTAL - 4

PART #2: FS: ADDITIONAL TONGUE BASE BIOPSY [REDACTED]

Resident Pathologist: [REDACTED]

FROZEN SECTION DIAGNOSIS:

Staff Pathologist: [REDACTED]

Other Pathologists [REDACTED]

FS: Additional tongue base biopsy: Scattered markedly atypical cells, defer to permanents.

Dictated by: [REDACTED]

The specimen is received fresh for frozen section, labeled with the patient's name, [REDACTED] and designated 'additional tongue base biopsy.' The specimen consists of multiple tan portions of soft tissue aggregating to 0.5 x 0.5 x 0.4 cm, which is entirely frozen. The specimen is wrapped in lens paper and entirely submitted.

SUMMARY OF SECTIONS

1 - FSC - MULTIPLE
1 - TOTAL - M

PART #3: LEFT TONGUE BIOPSY [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received in saline labeled with the patient's name, [REDACTED] and designated 'left tongue biopsy.' The specimen consists of several small fragments of white-tan soft tissue measuring 0.5 x 0.5 x 0.2 cm in aggregate. The specimen is submitted in its entirety in lens paper.

SUMMARY OF SECTIONS

1 - A - MULTIPLE
1 - TOTAL - M

PART #4: LEVEL 2 AND 3 RIGHT NECK [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

[REDACTED] FINAL DOCUMENT [REDACTED]

[page 3 of 3]
The specimen is received fresh labeled with the patient's name, [REDACTED] and designated 'Levels 2 and 3 right neck.' The specimen consists of a piece of red-tan soft tissue measuring 4.0 x 3.0 x 1.0 cm in size. The specimen is not oriented. Multiple lymph nodes are identified in the specimen. The largest lymph node measures 2.5 x 1.5 x 1.0 cm in size. The largest lymph nodes were bisected and the cut surface is white-tan and homogeneous. Three other small lymph nodes are identified. The specimen is submitted in its entirety.

SUMMARY OF SECTIONS

3 - A-C - 1 EACH (1 LN)
3 - D-F - 1 EACH (3 SMALL LNS)
4 - G-J - 1 EACH (SOFT TISSUE)
10 - TOTAL - M

PART #5: LEVEL 1 LYMPH NODE [REDACTED]

Resident Pathologist: [REDACTED]

Dictated by: [REDACTED]

The specimen is received fresh, labeled with the patient's name, [REDACTED] and designated 'Level 1 lymph node.' The specimen consists of a piece of red-tan soft tissue measuring 0.8 x 0.5 x 0.4 cm in size. The specimen was bisected and entirely submitted.

SUMMARY OF SECTIONS

1 - A - 2
1 - TOTAL - 2

=====

(End of Report) [REDACTED]

Note: This note provides information pertaining only to a specific event. A more detailed medical history is available in the Medical Record.

[REDACTED] FINAL DOCUMENT [REDACTED]

Source: NCI Genomic Data Commons file 1f01d3d5-4318-46fd-988e-01c32036b1c0 (TCGA-BB-7861.A2F70F7A-C3C2-4DDC-9BFC-1B95DA120E8F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).